CGCI case BLGSP-71-19-00119 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/913dca43-eeed-4efb-a07d-db1177271a65

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Age at index: 12 years.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 12.6 years (4,613 days); Year of diagnosis: 2001; Method of diagnosis: Bone Marrow Aspirate; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 4,530 days (12.4 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Bone marrow; Sites of involvement: Bone, NOS / Bone marrow / Testes / Lung, NOS / Small intestine.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Mediastinal.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 4,530 days (12.4 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD10: Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD3 (IHC): Negative.
- CD3: Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Lactate Dehydrogenase 1763 [Blood test normal range upper: 770].

Other clinical attributes
- Day 0: Weight: 50 kg; Height: 165 cm; BMI: 18.4.

Biospecimens (3 samples)
- Sample BLGSP-71-19-00119-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00119-09A.1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Sorted Cells; Preservation method: Frozen; Tissue collection type: Retrospective.
- Sample BLGSP-71-19-00119-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen; Days to sample procurement: 3,002 days (8.2 years); Method of sample procurement: Blood Draw; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: Yes; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Small non-cleaved cell - ALL-L3; Extranodal site involvement: 5; Extranodal involvment other: cecum; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 1763.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD3.
